FM case AD14407 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/d6872944-0e7d-40e3-95fa-a1fdb2ecba01

Female, 57.3 years: Mucinous carcinoma (ICD-O-3 8480/3) of the appendix; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
